Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GQ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GQ-06A (Metastatic).

[page 1 of 2]
ICD 0-3

Melanoma NOS 8720/3
Site: Small bowel NOS
C17.9

JW 11/27/13

DIAGNOSIS

A) PERITONEAL NODULE:

Fibroadipose tissue, no evidence of malignancy.

B) SMALL BOWEL TUMOR:

METASTATIC MALIGNANT MELANOMA INVOLVING SMALL INTESTINE AND PERI-INTESTINAL ADIPOSE TISSUE.

Proximal and distal resection margins are free of tumor.

Two lymph nodes, no tumor present (0/2).

C) RIGHT COLON:

Cecal tubulovillous adenoma with focal high grade dysplasia (5.5 CM).

Small tubular adenomas x2 in right colon.

Proximal ileal margin and distal colonic margin are free of tumor.

Appendix, no pathological change.

Thirty regional lymph nodes, no tumor present (0/30).

Entire report and diagnosis completed by

COMMENT

The cecal tubulovillous adenoma has a small area of squamous metaplasia. Immunohistochemical studies show that the adenoma cells in this area are negative for neuroendocrine markers synaptophysin, chromogranin, and CD56 and are positive for CK 5/6.

GROSS DESCRIPTION

(A) PERITONEAL NODULE - A 1.8 x 1.1 x 0.4 cm unoriented adipose tissue fragment is entirely submitted for frozen section in A.

*FS/DX: FIBROADIPOSE TISSUE.

(B) SMALL BOWEL TUMOR - A segment of small intestine, 30.0 cm in length with minimal attached adipose, up to 0.9 cm in maximum thickness.

An exophytic, circumferential, 12.8 x 8.5 x 3.3 cm mass is present, 11.5 and 12.5 cm from the margins of resection. The mass is variegated, predominantly gray-white with cystic areas, hemorrhage and black-gray discoloration. The mass extends through the intestinal wall and extensively involves the serosal surface and regional adipose.

The uninvolved mucosa is brown-tan. Two brown-tan lymph nodes, 0.3 cm are identified.

INK CODE: Blue-serosal surface.

SECTION CODE: B1-B3, a representative tumor, for frozen; B4, B5, margins, en face; B6-B11, representative tumor, all with serosal surface (B6, B7, B9, B11, with adjacent uninvolved mucosa); B12, two intact lymph nodes.

*FS/DX: CONSISTENT WITH METASTATIC MELANOMA.

(C) RIGHT COLON - A right hemicolectomy specimen (27.0 x 8.1 x 1.0 cm) including a colon (19.0 x 8.1 x 0.8 cm), terminal ileum (6.0 x 4.5 x 1.0 cm), appendix (7.0 x 0.5 x 0.5 cm).

Located in the cecum, 15.0 cm from the distal margin and 7.0 cm from the proximal margin, is a 5.5 x 4.5 x 1.0 cm polypoid, friable mass with a nodular surface. The mass does not grossly invade into the muscularis propria and does not involve the appendix.

Two separate polypoid nodules (0.7 cm in diameter and 0.5 cm in diameter) are identified, located 3.5 cm and 7.0 cm from the main polypoid mass respectively. The distal most polyp is 12.5 cm from the distal margin.

The appendix, terminal ileum, and the remaining colonic mucosa are unremarkable. The serosa is without obvious metastatic deposits or nodules.

Multiple possible lymph nodes are identified in adipose tissue (0.1 x 0.1 x 0.1 cm to 1.2 x 0.7 x 0.6 cm).

INK CODE: Black - serosa.

SECTION CODE: C1, proximal margin, en face; C2, C3, distal margin, en face; C4, appendix, tip; C5, appendix, mid sections, representative; C6, base of appendix; C7-C25, sections of the cecal polypoid mass, entirely blocked, including the deep serosa (C18 and C19 contiguous sections; C20 and C21, contiguous sections); C26, polypoid nodule closest to the main cecal

[page 2 of 2]
nass; C27 and C28, polyp, distal most, entirely submitted; C29, representative section-terminal ileum; C30, representative section-normal colon; C31, three possible lymph nodes.

C32, one lymph node trisected; C33, one lymph node trisected; C34, three lymph nodes; C35, four lymph nodes; C36, six lymph nodes; C37, six lymph nodes; C38, three lymph nodes.

CLINICAL HISTORY

History of malignant melanoma at right upper back.

SNOMED CODES

T-58000, T-59100, M-82630, M-Y4030, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration." These tests have not been

Released by:

-----END OF REPORT-----

Criteria	lw 10/28/13	Yes	No
Prior Discrepancy History			✓

Source: NCI Genomic Data Commons file c6065d08-2782-4ab3-865b-4435b2833181 (TCGA-D3-A8GQ.73155A8A-95D1-4F01-9DC5-561B6E9CAEA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).